Gene-level copy-number profile of tumor specimen TCGA-UF-A71E-01A from TCGA case TCGA-UF-A71E, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Floor of mouth, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G3; Age at diagnosis: 63.2 years (23,071 days).
Specimen TCGA-UF-A71E-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.f441001e-e536-4069-baae-b400ae5f7684.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-UF-A71E-10B (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 811 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/cea5f4f2-acf9-49c2-a1cc-42f0586c9f75

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 24; copy number 1: 922; copy number 2: 25,174; copy number 3: 20,863; copy number 4: 8,522; copy number 5: 1,895; copy number 6: 1,311; copy number 7: 980; copy number 8: 7; copy number 9: 1; copy number 13: 4; copy number 14: 25; copy number 20: 22; copy number 22: 21; copy number 27: 34; copy number 29: 7.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-UF-A71E-01A-31D-A34I-01): tumor purity 0.67, ploidy 2.9, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 23 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:11,745–858,091, 12 genes: LINC01986, AC066595.1, CHL1-AS2, AC066595.2, CHL1, RNU6-1194P, RPS8P6, CHL1-AS1, AC087428.1, LINC01266, RPSAP32, AC090044.1.
- chr9:21,802,636–22,029,594, 1 gene (within-gene range 0–2): AL359922.1.
- chr9:21,929,457–22,128,103, 8 genes (within-gene range 0–2): ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1.
- chr13:110,340,958–110,341,029, 1 gene: MIR8073.
- chr17:9,171,068–9,179,118, 1 gene: AC005695.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 4,307 genes in 22 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:163,509,484–164,899,296, 11 genes, copy number 5 (within-gene range 4–5): RNA5SP63, AL355862.1, U3, NMNAT1P2, RNU5F-6P, HMGB3P6, PBX1, RNU6-171P, AL391001.1, Metazoa_SRP, PBX1-AS1.
- chr1:176,857,302–178,038,007, 8 genes, copy number 5 (within-gene range 4–5): ASTN1, MIR488, BRINP2, LINC01645, AL136114.1, LINC01741, SEC16B, CRYZL2P-SEC16B.
- chr1:178,017,127–178,017,343, 1 gene, copy number 5: AL359075.1.
- chr2:48,809,340–49,419,013, 1 gene, copy number 6 (within-gene range 3–6): AC009975.1.
- chr2:49,202,126–53,486,280, 32 genes, copy number 5–6: AC009975.2, RNU6-439P, AC009971.1, RPL7P13, SNORA75, NRXN1, AC068725.1, MTCO1P42, AC009234.1, MIR8485, AC007560.1, AC007682.1, AC007402.1, AC007402.2, KNOP1P3, CRYGGP, AC097463.1, CCDC12P1, AC079304.1, ZNF863P, Y_RNA, LINC01867, GGCTP3, AC139712.1, CRTC1P1, FTH1P6, MIR4431, AC010967.1, AC010967.2, AC010967.3, AC069157.2, AC069157.1.
- chr2:76,106,016–76,399,490, 5 genes, copy number 9–13: SUCLA2P2, AC073091.1, AC073091.2, PNPP1, USP21P2.
- chr3:14,675,141–14,948,424, 6 genes, copy number 6 (within-gene range 2–6): C3orf20, AC090957.1, AC087591.1, LINC02011, FGD5, FGD5-AS1.
- chr3:88,948,142–198,222,513, 1,812 genes, copy number 5–7 (within-gene range 4–7) (broad region; genes not listed).
- chr7:12,211,270–15,068,651, 27 genes, copy number 5: TMEM106B, VWDE, AC013470.3, AC013470.2, SSBL5P, TAS2R2P, AC013470.1, AC005281.1, SCIN, AC011891.2, AC011891.3, ARL4A, AC011891.1, AC011287.1, RN7SKP228, RBMX2P4, AC011287.2, AC005019.2, AC005019.1, ETV1, Y_RNA, RPL6P21, DGKB, EEF1A1P26, AC006150.1, GTF3AP5, AC006458.1.
- chr7:42,661,716–56,848,800, 277 genes, copy number 5–6 (within-gene range 3–6) (broad region; genes not listed).
- chr8:67,952,046–69,178,189, 14 genes, copy number 5: PREX2, AC011853.2, AC011853.1, Y_RNA, RPL31P40, C8orf34-AS1, C8orf34, RPS15AP25, RNA5SP269, AC083967.1, LINC01592, RNU7-102P, AF201337.1, AC021785.1.
- chr8:86,866,415–139,127,953, 700 genes, copy number 5–6 (within-gene range 4–6) (broad region; genes not listed).
- chr9:68,328,308–68,531,061, 1 gene, copy number 5 (within-gene range 4–5): PGM5.
- chr9:68,393,881–119,524,125, 809 genes, copy number 5 (broad region; genes not listed).
- chr11:68,612,899–70,436,584, 55 genes, copy number 20–27: AP003096.1, GAL, TESMIN, CPT1A, LINC02701, MRPL21, IGHMBP2, AP000808.1, MRGPRD, AP003071.4, AP003071.3, MRGPRF, MRGPRF-AS1, TPCN2, AP003071.5, MIR3164, AP003071.1, AP003071.2, SMIM38, MYEOV, IFITM9P, AP005233.2, AP005233.1, AP000439.2, AP000439.1, AP000439.3, LINC02747, LINC01488, CCND1, LTO1, FGF19, DNAJB6P5, FGF4, FGF3, AP007216.1, AP007216.2, AP003555.2, AP003555.1, LINC02753, LINC02584, RNU6-1175P, ANO1, AP000879.2, ANO1-AS1, FADD, AP000879.1, PPFIA1, H2AZP4, AP002336.2, MIR548K, AP002336.1, AP002336.3, AP000487.2, AP000487.1, CTTN.
- chr11:70,477,277–70,477,592, 1 gene, copy number 20: AP001271.1.
- chr12:33,576,095–34,249,958, 14 genes, copy number 6: RNU6-400P, AC024153.1, RNU6-472P, Y_RNA, AC046130.1, ALG10, AC046130.2, AC140847.1, AC140847.3, TUBB8P4, AC140847.2, RNA5SP357, DUX4L27, AK6P1.
- chr14:34,981,957–37,552,361, 60 genes, copy number 8–29 (within-gene range 2–29): SRP54, FAM177A1, PPP2R3C, AL049776.1, PRORP, AL121594.1, RPL23AP70, SEPTIN7P1, MRPL57P8, DPRXP3, RPL7AP3, RPL9P3, PSMA6, AL133163.2, AL133163.1, NFKBIA, DNAJC8P1, AL133163.3, RPS3AP4, KRT18P6, INSM2, RALGAPA1, AL137818.1, QRSL1P3, AL162311.3, NUTF2P2, BRMS1L, AL162311.1, AL162311.2, AL133304.3, AL133304.1, ILF2P2, AL133304.2, LINC00609, PTCSC3, AL162511.1, RN7SKP21, MBIP, AL132857.1, DPPA3P2, RNU7-93P, SFTA3, SFTA3, NKX2-1, NKX2-1-AS1, PHKBP2, RPL29P3, NKX2-8, RN7SKP257, AL079303.1, PAX9, SLC25A21, AL162464.2, AL162464.1, MIR4503, AL079304.1, SLC25A21-AS1, RNU6-273P, MIPOL1, RNU6-886P.
- chr15:83,654,088–101,933,350, 440 genes, copy number 5–6 (within-gene range 3–6) (broad region; genes not listed).
- chr16:5,239,802–7,713,340, 1 gene, copy number 5 (within-gene range 4–5): RBFOX1.
- chr16:5,632,467–8,112,756, 17 genes, copy number 5 (within-gene range 4–5): MIR8065, AC012175.1, AC009135.2, AC009135.1, AC006112.1, AC007223.1, AC007012.2, AC007012.1, RNU7-99P, RNU6-457P, RNU6-328P, AC022206.1, AC007222.2, AC007222.1, AC005774.2, AC005774.1, AC093515.1.
- chr19:22,017,898–22,317,176, 15 genes, copy number 7 (within-gene range 3–7): AC003973.1, ZNF257, BNIP3P29, ZNF92P2, AC073539.2, PCGF7P, MTDHP5, VN1R85P, ZNF676, BNIP3P30, AC073539.14, AC073539.1, AC073539.3, ZNF729, BNIP3P31.

Autosomal genes at a single copy (total copy number 1): 35. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
